Somatic mutation profile of tumor specimen TARGET-20-PASGCJ-03A (aliquot TARGET-20-PASGCJ-03A-01D) from TARGET case TARGET-20-PASGCJ, project TARGET-AML (Acute Myeloid Leukemia). Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow.
Specimen TARGET-20-PASGCJ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55b5d92f-11c8-4258-849a-f2c5cc259649.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASGCJ-14A (Bone Marrow Normal), aliquot TARGET-20-PASGCJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a90f996-ca15-4a47-a6b9-3d5525d51970

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.521G>A p.R174Q (on ENST00000344691 / NM_001001890.3; = p.R201Q on NM_001754.5) | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs74315450, CM992140, COSV55867719, COSV55890900; ClinVar: pathogenic; called by muse, varscan2
- WT1 | c.1105_1108dup p.A370Vfs*4 | Frame Shift Ins (INS) | VAF 70/208 reads (34%) | catalogued as COSV60065440; called by mutect2, varscan2
